Somatic mutation profile of tumor specimen C3N-00880-01 (aliquot CPT0078710010) from CPTAC case C3N-00880, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.4 years (22,438 days).
Specimen C3N-00880-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b044052-2fba-4205-b8fe-8f6d95f66ee9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00880-31 (Blood Derived Normal), aliquot CPT0078790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c92eaa61-332c-4e6a-953b-ac3128cd04d4

The open-access MAF lists 935 somatic variants for this specimen: 627 protein-altering or splice-affecting, 198 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 416, Silent 198, Frame Shift Del 125, Intron 54, Nonsense Mutation 35, Frame Shift Ins 26, 3'UTR 18, RNA 15, Splice Site 14, 5'UTR 11, Splice Region 7, 3'Flank 6.

Variants (750 of 935; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD3D | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 144/648 reads (22%) | catalogued as rs111033580, CM032865; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPT1A | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 48/377 reads (13%) | catalogued as rs773153659, COSV55754371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/689 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 208/286 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1214_1216del p.I405del (on ENST00000521381 / NM_181523.3; = p.I135del on NM_181504.4) | In Frame Del (DEL) | VAF 18/160 reads (11%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 176/545 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SAMHD1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 69/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs515726145, CM093963, COSV99483854; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UBE3B | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | catalogued as rs746058354, COSV99784492; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.2734G>A p.A912T (on ENST00000326724 / NM_001080395.3; = p.A809T on NM_004920.2) | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs1380397925; called by muse, mutect2
- ABCA1 | c.4196C>T p.T1399M | Missense Mutation (SNP) | VAF 119/533 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs199668464, COSV66064398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC024592.3 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs371542591; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS9 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 21/508 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV55791162; called by muse, mutect2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 17/139 reads (12%) | catalogued as rs764604854; called by mutect2, varscan2
- ALB | c.1289+1G>A p.X430_splice | Splice Site (SNP) | VAF 80/217 reads (37%) | catalogued as rs779988470, CS122001, COSV55735420, COSV55742076; called by muse, mutect2, varscan2
- ALDH3A1 | c.589A>T p.M197L | Missense Mutation (SNP) | VAF 141/404 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs752901351, COSV56734897; called by muse, mutect2, varscan2
- ALG13 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1057521748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH5 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315958769, COSV67687169; called by muse, mutect2, varscan2
- ANKK1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as rs373295480, COSV58273538; called by muse, mutect2, varscan2
- ANKRD17 | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442131714, COSV58227285; called by muse, mutect2
- ANKRD52 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1296370094; called by muse, mutect2, varscan2
- AP3M2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750901629, COSV51530426; called by muse, mutect2, varscan2
- ARHGAP21 | c.5395C>T p.R1799W | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs768755069, COSV100256513; called by muse, mutect2, varscan2
- ASMTL | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765713718; called by muse, mutect2
- ATP13A4 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV55074706; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 45/409 reads (11%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- AXL | c.1703C>T p.T568M (on ENST00000301178 / NM_021913.5; = p.T559M on NM_001699.6) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749923407, COSV56575042; called by muse, mutect2
- BACE2 | c.1501del p.R501Vfs*20 | Frame Shift Del (DEL) | VAF 47/283 reads (17%) | catalogued as COSV100160427; called by mutect2, pindel, varscan2
- BACH1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs139702208; called by muse, varscan2
- BCL6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 14/255 reads (5%) | catalogued as COSV99215688; called by muse, mutect2
- BCOR | c.2941A>G p.T981A | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60715378; called by muse, mutect2, varscan2
- BHLHE40 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as rs771342311; called by muse, mutect2, varscan2
- BRINP3 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100819281; called by muse, mutect2, varscan2
- BVES | c.1001C>A p.P334Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1048385415, COSV58949897; called by muse, mutect2, varscan2
- CAND2 | c.2773G>A p.A925T (on ENST00000456430 / NM_001162499.2; = p.A832T on NM_012298.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs774791381, COSV55990577, COSV99929833; called by muse, mutect2, varscan2
- CAPSL | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs375106222; called by muse, mutect2, varscan2
- CASP12 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs1455679820; called by muse, mutect2, varscan2
- CCDC102B | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.639); catalogued as COSV60138267, COSV60140705; called by muse, mutect2, varscan2
- CCL17 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs550625736; called by muse, mutect2, varscan2
- CCT6B | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 30/146 reads (21%) | catalogued as rs139127098; called by muse, mutect2, varscan2
- CCZ1B | c.390+5T>C | Splice Region (SNP) | VAF 15/75 reads (20%) | catalogued as rs1329054207; called by muse, mutect2, varscan2
- CD70 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs780084590, COSV104368694; called by muse, mutect2, varscan2
- CD79A | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 131/556 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as rs374041941; called by muse, mutect2, varscan2
- CDC42BPB | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145670721; called by muse, mutect2, varscan2
- CDC7 | c.126del p.D43Ifs*39 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV99319917; called by mutect2, pindel, varscan2
- CDT1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773495319; called by muse, mutect2, varscan2
- CECR2 | c.4006G>A p.E1336K (on ENST00000342247 / NM_001290047.2; = p.E1152K on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1375676607, COSV52844056; called by muse, mutect2
- CEP295NL | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs978770019; called by muse, mutect2, varscan2
- CERT1 | c.264del p.T89Hfs*85 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs893362976; called by mutect2, pindel, varscan2
- CHAF1A | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1302684208; called by muse, mutect2
- CHEK1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV54025050; called by muse, mutect2, varscan2
- CHRNB4 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55718367; called by muse, mutect2
- CHST11 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs371299013; called by muse, mutect2
- CLK4 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs529524184, COSV104412669; called by muse, mutect2, varscan2
- CLSPN | c.1005-1G>T p.X335_splice | Splice Site (SNP) | VAF 17/75 reads (23%) | catalogued as COSV52055733; called by muse, mutect2, varscan2
- COL11A1 | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV62186769; called by muse, mutect2, varscan2
- COL12A1 | c.5770C>T p.R1924C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs775862147, COSV59399602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs141909615; called by muse, mutect2, varscan2
- CPZ | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs780396225, COSV100249350; called by muse, mutect2, varscan2
- CRLF1 | c.713del p.P238Rfs*6 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | catalogued as COSV62260461; called by mutect2, pindel, varscan2
- CRYGD | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1283423785, COSV52205236; called by muse, mutect2, varscan2
- CTSD | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 41/536 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs377696355; called by muse, mutect2
- CTU2 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs371031341; called by muse, mutect2, varscan2
- CYP17A1 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1360144239; called by muse, mutect2, varscan2
- DCAF8L2 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); catalogued as COSV70548483; called by muse, varscan2
- DCTN2 | c.526C>T p.R176C (on ENST00000548249 / NM_001261413.2; = p.R181C on NM_006400.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1315316427, COSV63072755, COSV63073084, COSV63074718; called by muse, mutect2, varscan2
- DDAH2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs752006519, COSV65383552; called by muse, mutect2, varscan2
- DDX56 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs375038290; called by muse, mutect2
- DENND1B | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs899763529; called by muse, mutect2, varscan2
- DHRS7B | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752311534; called by muse, mutect2, varscan2
- DMAP1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs762372274, COSV60000516; called by muse, mutect2, varscan2
- DMD | c.8315C>T p.A2772V | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs758105917; called by muse, mutect2, varscan2
- DMD | c.3046C>T p.R1016W | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs199808421; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.1680_1681del p.R560Sfs*32 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs764308104; called by pindel, varscan2
- DNAH5 | c.13502G>C p.R4501P | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54225539, COSV54229233; called by muse, mutect2, varscan2
- DPYS | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100680266; called by muse, mutect2, varscan2
- DSG4 | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57394862; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | catalogued as rs35805169; called by mutect2, varscan2
- DYNC1H1 | c.11600C>T p.A3867V | Missense Mutation (SNP) | VAF 126/541 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs757163052, COSV64137377; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 50/191 reads (26%) | catalogued as rs369293935; called by mutect2, varscan2
- ECEL1 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs371924008; called by muse, mutect2, varscan2
- ELOA2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 51/598 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.464); catalogued as rs1416783971; called by muse, mutect2
- EPB41L4A | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99813554; called by muse, varscan2
- EPHB6 | c.2648del p.P883Rfs*37 | Frame Shift Del (DEL) | VAF 73/300 reads (24%) | catalogued as COSV100844458; called by mutect2, pindel, varscan2
- ERF | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV55897335; called by muse, mutect2
- EXD3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs200247361; called by muse, mutect2, varscan2
- F8 | c.233del p.F78Sfs*14 | Frame Shift Del (DEL) | VAF 93/494 reads (19%) | catalogued as CD123863; called by mutect2, pindel, varscan2
- FAM47B | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 31/521 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as COSV61453766; called by muse, mutect2
- FAM71E1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs200164216; called by muse, mutect2, varscan2
- FBH1 | c.2398C>T p.Q800* (on ENST00000362091 / NM_178150.3; = p.Q851* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 9/157 reads (6%) | catalogued as rs1236088581, COSV62984836; called by muse, mutect2
- FBRS | c.1289C>T p.P430L (on ENST00000287468; = p.P950L on NM_001105079.3) | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs771936732; called by muse, mutect2, varscan2
- FBXO31 | c.188del p.P63Rfs*98 | Frame Shift Del (DEL) | VAF 30/147 reads (20%) | catalogued as rs1383917214; called by mutect2, pindel, varscan2
- FLNA | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61040689; called by muse, mutect2, varscan2
- FLNC | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV100368750; called by muse, mutect2, varscan2
- FNBP1L | c.1738C>T p.R580W (on ENST00000271234 / NM_001164473.2; = p.R522W on NM_017737.5) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766179132; called by muse, mutect2, varscan2
- FOXC1 | c.1491C>A p.Y497* | Nonsense Mutation (SNP) | VAF 34/266 reads (13%) | catalogued as CM117353; called by muse, varscan2
- FSIP2 | c.16148C>A p.A5383D | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV100555631; called by muse, mutect2, varscan2
- FUT2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs754989277; called by muse, mutect2, varscan2
- FZD1 | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55309699; called by muse, mutect2
- GABRP | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs756793352; called by muse, mutect2, varscan2
- GAPDH | c.586_587del p.W196Afs*2 | Frame Shift Del (DEL) | VAF 32/151 reads (21%) | catalogued as rs778058544; called by pindel, varscan2
- GATA1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.361); catalogued as rs149753411, COSV64962676; called by muse, mutect2
- GATAD2A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1367096298; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs750227570; called by mutect2, varscan2
- GLI2 | c.1435C>T p.R479* (on ENST00000361492 / NM_001374353.1; = p.R496* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/226 reads (7%) | catalogued as CM032935; called by muse, mutect2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 32/155 reads (21%) | catalogued as rs370114090; called by mutect2, varscan2
- GPBP1 | c.829_831del p.P277del | In Frame Del (DEL) | VAF 32/91 reads (35%) | catalogued as rs992774076; called by mutect2, pindel, varscan2
- GPSM2 | c.1440+5G>A | Splice Region (SNP) | VAF 58/286 reads (20%) | catalogued as rs751248763, COSV51441710; called by muse, mutect2, varscan2
- GRAP2 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275531139, COSV104417482; called by muse, mutect2, varscan2
- GRK5 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs141365148; called by muse, mutect2, varscan2
- GSTM5 | c.111C>T p.D37= | Splice Region (SNP) | VAF 18/324 reads (6%) | catalogued as rs1276733007, COSV99859808; called by muse, mutect2
- HAUS5 | c.118del p.A40Lfs*39 | Frame Shift Del (DEL) | VAF 51/245 reads (21%) | catalogued as rs984276080; called by mutect2, pindel, varscan2
- HDAC7 | c.2756_2758del p.E919del (on ENST00000427332; = p.E958del on NM_015401.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 29/123 reads (24%) | catalogued as rs769122679; called by pindel, varscan2
- HGFAC | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs200907783; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs761272507; called by mutect2, varscan2
- HPS5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772160206, COSV56378344; called by muse, mutect2
- IDNK | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751798667, COSV99461959; called by muse, mutect2, varscan2
- IFFO2 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100841968; called by muse, mutect2
- IFT172 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs367806691; called by muse, mutect2, varscan2
- IGSF10 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs569321772, COSV56790447; called by muse, mutect2
- IL1RAP | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150231780; called by muse, mutect2, varscan2
- INPPL1 | c.3470del p.G1157Dfs*45 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs1565399032, COSV53356328, COSV99996061; called by mutect2, pindel, varscan2
- INSRR | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV100947205; called by muse, mutect2
- IRS1 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs375677810; called by muse, mutect2, varscan2
- IRS2 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1057110627; called by muse, mutect2, varscan2
- ITGB2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs778870549; called by muse, mutect2, varscan2
- ITIH6 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as rs527740087, COSV99513462; called by muse, mutect2, varscan2
- KATNAL2 | c.1399G>T p.D467Y (on ENST00000356157 / NM_001353899.1; = p.D395Y on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99796282; called by muse, mutect2, varscan2
- KATNIP | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs143686832; called by muse, mutect2, varscan2
- KBTBD6 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 33/528 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as COSV65271910; called by muse, mutect2
- KDM5A | c.4154A>G p.E1385G | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66995449; called by muse, varscan2
- KIAA0319L | c.1224dup p.I409Hfs*21 | Frame Shift Ins (INS) | VAF 36/176 reads (20%) | catalogued as rs775373228; called by mutect2, pindel, varscan2
- KIFBP | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62555580; called by muse, mutect2
- KLF16 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464155965, COSV51736425; called by muse, mutect2
- KMT2B | c.3145del p.A1049Rfs*133 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV55869560; called by mutect2, pindel
- KRT79 | c.339del p.I114Sfs*11 | Frame Shift Del (DEL) | VAF 13/148 reads (9%) | catalogued as rs954629041; called by mutect2, pindel
- KRTAP4-5 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs761495551; called by muse, varscan2
- LCN8 | c.160C>T p.R54W (on ENST00000612714 / NM_001345934.1; = p.R31W on NM_178469.3) | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201335726; called by muse, mutect2, varscan2
- LPA | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 132/554 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100306552; called by muse, mutect2, varscan2
- LRP2 | c.13936G>A p.A4646T | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202210831, COSV55553055; called by muse, mutect2
- LSG1 | c.1457C>T p.T486I | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV99503427; called by muse, mutect2, varscan2
- LSM14B | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 58/445 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1413115921; called by muse, mutect2, varscan2
- LTBP2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 132/593 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1313818466, COSV100001374, COSV56212326; called by muse, mutect2, varscan2
- LTBP3 | c.678del p.V227Wfs*2 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs1349589786; called by mutect2, pindel, varscan2
- LUZP4 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs782712614; called by muse, mutect2, varscan2
- LZTS2 | c.1971del p.C658Afs*34 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as COSV64651535; called by mutect2, pindel, varscan2
- MAGEL2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.946); catalogued as rs930141240; called by muse, mutect2
- MAP3K14 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs367798756; called by muse, mutect2, varscan2
- MAP3K4 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as rs763787914; called by muse, mutect2, varscan2
- MAP7D1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60215658; called by muse, mutect2, varscan2
- MAP7D1 | c.2255G>T p.R752L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60217761; called by muse, mutect2, varscan2
- MBD1 | c.1535G>T p.G512V (on ENST00000269468 / NM_001323950.1; = p.G456V on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/672 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs753804798; called by muse, mutect2
- MBD6 | c.1674_1675del p.H558Qfs*16 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs929416597; called by pindel, varscan2
- MCHR1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 148/724 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs201703342; called by muse, mutect2, varscan2
- MED1 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs781080330; called by muse, mutect2
- MEGF6 | c.3842dup p.R1283Efs*7 | Frame Shift Ins (INS) | VAF 28/119 reads (24%) | catalogued as rs1557714133; called by pindel, varscan2
- METAP2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 28/173 reads (16%) | catalogued as COSV54148225; called by muse, mutect2, varscan2
- METTL14 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755748754; called by muse, mutect2, varscan2
- MIEF2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs757411084; called by muse, mutect2, varscan2
- MKKS | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 89/385 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1451914942, COSV104417083; called by muse, mutect2, varscan2
- MMP11 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99303164; called by muse, mutect2, varscan2
- MTOR | c.4171C>G p.R1391G | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100815589, COSV63874955; called by muse, mutect2, varscan2
- MUC5AC | c.15397G>A p.G5133R | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT tolerated, low confidence (0.24); catalogued as rs768459780; called by muse, mutect2, varscan2
- MYH14 | c.3874C>T p.R1292* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as rs577038007; called by muse, mutect2, varscan2
- MYH7 | c.4394C>T p.S1465L | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.228); catalogued as rs1033511138, CM115871, COSV62523799; called by muse, mutect2
- NDST4 | c.1813dup p.T605Nfs*22 | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | catalogued as rs1215333204; called by mutect2, pindel, varscan2
- NEB | c.3302G>A p.G1101D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs368377514; called by muse, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as rs759081520; called by mutect2, pindel
- NFX1 | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.406); catalogued as COSV100780885; called by muse, mutect2, varscan2
- NLGN4X | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 43/569 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs727504050, COSV52014891; ClinVar: uncertain significance; called by muse, mutect2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 9/46 reads (20%) | catalogued as rs765400964; called by mutect2, pindel
- NOTCH3 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 83/588 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as CM046101, COSV54636886; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as rs1167519601; called by pindel, varscan2
- NRN1L | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as rs376155637; called by muse, mutect2
- NUP133 | c.2786del p.L929Cfs*18 | Frame Shift Del (DEL) | VAF 28/266 reads (11%) | catalogued as rs1433526651; called by mutect2, pindel
- OPRD1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1403111738; called by muse, mutect2, varscan2
- OR2A14 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1481069147, COSV68718411; called by muse, mutect2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR7C2 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 28/331 reads (8%) | catalogued as rs747041500; called by mutect2, pindel
- OR9A4 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs1362463100; called by muse, mutect2
- ORC3 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs930774313; called by muse, mutect2
- P4HTM | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs146471142; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 38/130 reads (29%) | catalogued as rs757903860; called by mutect2, varscan2
- PCDHB5 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV50653087, COSV50669649; called by muse, mutect2, varscan2
- PCNT | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV64024604; called by muse, mutect2, varscan2
- PDE11A | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs543188674, COSV53695378; called by muse, mutect2
- PDILT | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 25/465 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1191219964; called by muse, mutect2
- PER3 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 111/424 reads (26%) | catalogued as rs376773861, COSV62704880; called by muse, mutect2, varscan2
- PFKL | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205707513; called by muse, mutect2, varscan2
- PGF | c.73del p.Q25Sfs*83 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs756979630; called by mutect2, pindel, varscan2
- PGLYRP4 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs762332871; called by muse, mutect2, varscan2
- PHF3 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs763965577, COSV50356161; called by muse, mutect2, varscan2
- PHF7 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as rs762575967, COSV56233875, COSV56242215; called by muse, mutect2, varscan2
- PIK3C2B | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV65803504; called by muse, mutect2, varscan2
- PIK3C2G | c.192del p.F64Lfs*15 | Frame Shift Del (DEL) | VAF 52/198 reads (26%) | catalogued as COSV56841032; called by mutect2, varscan2
- PIK3CG | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as rs142380460, COSV63248889; called by muse, varscan2
- PIPOX | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs148024165; called by muse, mutect2, varscan2
- PKD2L1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1252130898; called by muse, mutect2
- PLA2G4E | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778619405; called by muse, mutect2, varscan2
- PLEC | c.8851G>A p.G2951S (on ENST00000322810 / NM_201380.4; = p.G2841S on NM_000445.5) | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782561172; called by muse, mutect2, varscan2
- PLEKHG6 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs374606602; called by muse, mutect2, varscan2
- PLEKHH3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs748154829; called by muse, mutect2, varscan2
- PLOD1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 62/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886045200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLSCR3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV61170631; called by muse, mutect2, varscan2
- PLSCR4 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs756473618; called by muse, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNB3 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs782559344, COSV62796555; called by muse, mutect2
- PLXNB3 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1396466475; called by muse, mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 26/119 reads (22%) | catalogued as rs751873496; called by mutect2, varscan2
- POLE4 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.262); catalogued as rs1044000584, COSV99284361; called by muse, mutect2, varscan2
- POLR1F | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1272881995; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 28/156 reads (18%) | catalogued as rs766639242; called by mutect2, varscan2
- PRB2 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as rs753085797, COSV66984202; called by muse, varscan2
- PRICKLE3 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs782007392; called by muse, mutect2, varscan2
- PRKAR2B | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV55924179; called by muse, mutect2, varscan2
- PSAT1 | c.1090T>A p.F364I (on ENST00000376588 / NM_058179.4; = p.F318I on NM_021154.5) | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179781327, COSV61301821; called by muse, mutect2, varscan2
- PSG11 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1477221341, COSV100106158; called by muse, varscan2
- PSKH1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs145190865; called by muse, mutect2, varscan2
- PSMA7 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as COSV53379040; called by muse, mutect2
- PTEN | c.912C>A p.C304* | Nonsense Mutation (SNP) | VAF 84/242 reads (35%) | catalogued as COSV64299610; called by muse, mutect2, varscan2
- PTF1A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1339056661, COSV64735082; called by mutect2, varscan2
- PTPN22 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194741881, COSV63085497, COSV63086509; called by muse, mutect2, varscan2
- PTPN6 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782645298; called by muse, mutect2, varscan2
- PTPRB | c.5692G>A p.G1898R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99719351; called by muse, varscan2
- PTPRU | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs763868325, COSV60529171; called by muse, mutect2, varscan2
- PXDN | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 95/482 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs117378371, COSV53241438, COSV53250146; called by muse, mutect2, varscan2
- RAD54L | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 142/555 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs797044888, COSV64335738; called by muse, mutect2, varscan2
- RASA1 | c.434dup p.L146Ffs*12 | Frame Shift Ins (INS) | VAF 98/370 reads (26%) | catalogued as rs766715946; called by pindel, varscan2
- RASSF5 | c.114del p.D39Tfs*127 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | catalogued as rs1344667401; called by mutect2, varscan2
- RBBP8 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs370311825; ClinVar: uncertain significance; called by muse, mutect2
- RBL1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.311); catalogued as rs1416275736; called by muse, mutect2, varscan2
- RBM28 | c.809+3A>G | Splice Region (SNP) | VAF 51/388 reads (13%) | catalogued as rs1432908044; called by muse, mutect2, varscan2
- RBMXL3 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as rs782111364, COSV57751773; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIN3 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs868473834; called by muse, mutect2, varscan2
- RP1L1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 130/480 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs201625937; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 71/272 reads (26%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RSAD1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as rs940111556, COSV51955663; called by muse, mutect2, varscan2
- RTN3 | c.3089dup p.A1031Gfs*28 (on ENST00000377819 / NM_001265589.2; = p.A235Gfs*28 on NM_006054.4) | Frame Shift Ins (INS) | VAF 17/100 reads (17%) | catalogued as rs747510098; called by mutect2, varscan2
- SAR1A | c.516del p.M173Wfs*49 | Frame Shift Del (DEL) | VAF 36/230 reads (16%) | catalogued as COSV64699554; called by mutect2, pindel, varscan2
- SARM1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs372946020; called by muse, mutect2, varscan2
- SBF1 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs745551529; called by muse, mutect2, varscan2
- SCFD2 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101189300; called by muse, varscan2
- SCN1A | c.3478G>T p.G1160C (on ENST00000303395 / NM_001202435.3; = p.G1149C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs776752552, COSV57680577; called by muse, mutect2
- SCN1A | c.3053G>T p.R1018M (on ENST00000303395 / NM_001202435.3; = p.R1007M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318746, COSV57666912; called by mutect2, varscan2
- SEC16B | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs768838876, COSV57629327; called by muse, mutect2
- SETD7 | c.1026del p.K344Rfs*14 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs35259575; called by mutect2, varscan2
- SEZ6L | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as rs1286770959, COSV50662925; called by muse, mutect2, varscan2
- SGSM3 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773271072, COSV99960521; called by muse, mutect2, varscan2
- SHANK3 | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1309658357; called by muse, mutect2, varscan2
- SHKBP1 | c.134_136del p.F45del | In Frame Del (DEL) | VAF 37/183 reads (20%) | catalogued as rs767470501; called by pindel, varscan2
- SIGLEC11 | c.75G>A p.A25= | Splice Region (SNP) | VAF 18/82 reads (22%) | catalogued as rs891011191; called by muse, mutect2, varscan2
- SIPA1L1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1195717206; called by muse, mutect2
- SKIDA1 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV71610905; called by muse, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs767964038; called by mutect2, varscan2
- SLC24A3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs769765422, COSV60118640; called by muse, mutect2, varscan2
- SLC2A3 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 19/294 reads (6%) | catalogued as COSV50007385; called by muse, mutect2
- SLC32A1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV54147328; called by muse, mutect2, varscan2
- SLC34A3 | c.125C>G p.T42R | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.047); catalogued as rs1262519524; called by muse, varscan2
- SLC6A16 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs371386937, COSV100242922; called by muse, mutect2, varscan2
- SLCO2B1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV56938318; called by muse, mutect2
- SLTM | c.1539del p.E514Kfs*8 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs1319405514; called by mutect2, varscan2
- SMAD4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1555685159, COSV61685150; ClinVar: uncertain significance; called by muse, mutect2
- SMPDL3B | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV65854930; called by muse, mutect2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 31/144 reads (22%) | catalogued as rs768873484; called by mutect2, varscan2
- SORBS2 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs771002154; called by muse, mutect2, varscan2
- SOX18 | c.1023del p.L343Sfs*23 | Frame Shift Del (DEL) | VAF 61/339 reads (18%) | catalogued as COSV61110783; called by mutect2, pindel, varscan2
- SP110 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 110/502 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs372023963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPACA9 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV53771564; called by muse, mutect2, varscan2
- SPEG | c.3479C>T p.A1160V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV56669084; called by muse, mutect2, varscan2
- SPNS2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs374147635, COSV100223915; called by muse, mutect2, varscan2
- SPOCD1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99930457; called by muse, mutect2, varscan2
- SRGAP1 | c.3121A>T p.M1041L | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1398889045; called by muse, mutect2
- SRRM2 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 116/459 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs369700013; called by muse, varscan2
- SRRT | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs375882161; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 18/176 reads (10%) | PolyPhen probably damaging (0.917); catalogued as rs764607427, COSV100231617; called by muse, mutect2, varscan2
- STAMBP | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs538751950; called by muse, mutect2, varscan2
- SZT2 | c.1943dup p.N648Kfs*88 | Frame Shift Ins (INS) | VAF 14/125 reads (11%) | catalogued as COSV100986896; called by mutect2, pindel, varscan2
- TAC3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 119/587 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs909450876, COSV100269933; called by muse, mutect2, varscan2
- TAFA5 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.75); catalogued as rs1224471929, COSV60979953; called by muse, mutect2, varscan2
- TALDO1 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59796959, COSV59798314; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs763321097; called by mutect2, varscan2
- TFIP11 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs751148942; called by muse, mutect2, varscan2
- THEMIS | c.1218del p.V407Wfs*2 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | catalogued as rs1425728909; called by mutect2, pindel, varscan2
- THSD7A | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.074); catalogued as rs767395309, COSV70273978; called by muse, mutect2, varscan2
- TMEM184B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1444909539; called by muse, mutect2, varscan2
- TMEM30B | c.273del p.C92Afs*23 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs979697561; called by mutect2, varscan2
- TNC | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV60782832; called by muse, mutect2, varscan2
- TNFSF14 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs754946970; called by muse, mutect2
- TNK1 | c.1087del p.H363Tfs*26 | Frame Shift Del (DEL) | VAF 58/215 reads (27%) | catalogued as rs777072179; called by mutect2, pindel, varscan2
- TNS3 | c.2358del p.Q787Sfs*33 | Frame Shift Del (DEL) | VAF 51/240 reads (21%) | catalogued as COSV60787512; called by mutect2, varscan2
- TRANK1 | c.5128G>A p.A1710T | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs373949575; called by muse, mutect2, varscan2
- TRIB2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs980383457, COSV50225179; called by muse, mutect2, varscan2
- TRIL | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1160184865; called by muse, mutect2
- TRIM26 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.083); catalogued as rs147508131; called by muse, mutect2, varscan2
- TRIM38 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.35); catalogued as rs368108856, COSV62643184; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as rs763121810; called by mutect2, varscan2
- TRPC6 | c.2379del p.G794Vfs*8 | Frame Shift Del (DEL) | VAF 26/263 reads (10%) | catalogued as rs757567055; called by mutect2, pindel
- TTC8 | c.260C>A p.P87H (on ENST00000338104 / NM_001288781.1; = p.P97H on NM_144596.4) | Missense Mutation (SNP) | VAF 35/533 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57630524; called by muse, mutect2
- TUB | c.68G>T p.R23M (on ENST00000299506 / NM_177972.3; = p.R78M on NM_003320.4) | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs938944019; called by muse, mutect2
- UBA7 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765530016; called by muse, mutect2, varscan2
- UBE4B | c.2189C>T p.T730M (on ENST00000343090 / NM_001105562.3; = p.T601M on NM_006048.5) | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753923979; called by muse, mutect2
- UMOD | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs188397613, COSV56779747; called by muse, mutect2, varscan2
- UNC13B | c.4649G>A p.R1550Q | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as rs761059704; called by muse, mutect2, varscan2
- UVSSA | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as rs747905369; called by muse, mutect2
- VENTX | c.272C>G p.A91G | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58085041; called by muse, mutect2
- VIRMA | c.4712G>A p.R1571H | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs751267865, COSV52581476; called by muse, mutect2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 51/270 reads (19%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS33A | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.764); catalogued as COSV99931266; called by muse, mutect2, varscan2
- WFDC5 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as rs551709664, COSV100332194; called by muse, mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | catalogued as COSV53295493; called by mutect2, pindel, varscan2
- WWP2 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.529); catalogued as rs372517256; called by muse, mutect2, varscan2
- XDH | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 122/548 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV101052516, COSV65147258; called by muse, mutect2, varscan2
- ZBTB1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV62440060; called by muse, mutect2
- ZC3H4 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as rs757680989; called by muse, mutect2, varscan2
- ZIC3 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54975534; called by muse, mutect2, varscan2
- ZNF112 | c.1691G>A p.R564Q (on ENST00000337401 / NM_001083335.2; = p.R558Q on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as rs79226975; called by muse, mutect2
- ZNF133 | c.365C>T p.P122L (on ENST00000316358 / NM_001352454.2; = p.P121L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs199700098; called by muse, varscan2
- ZNF136 | c.252del p.F84Lfs*9 | Frame Shift Del (DEL) | VAF 35/156 reads (22%) | catalogued as rs1438062248; called by mutect2, pindel, varscan2
- ZNF143 | c.1191del p.R397Sfs*80 | Frame Shift Del (DEL) | VAF 100/264 reads (38%) | catalogued as COSV55181322; called by mutect2, pindel, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 34/172 reads (20%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- ZNF345 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs375817401, COSV59325717; called by muse, mutect2, varscan2
- ZNF497 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as rs766255019; called by muse, varscan2
- ZNF497 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV54050915; called by muse, mutect2
- ZNF500 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs561333559; called by muse, varscan2
- ZNF737 | c.183del p.K61Nfs*3 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as rs1224733412, COSV71199512; called by mutect2, pindel, varscan2
- ZNF780B | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as rs778557584, COSV55465860; called by muse, mutect2
- ZNF793 | c.862del p.C288Vfs*113 | Frame Shift Del (DEL) | VAF 47/247 reads (19%) | catalogued as rs761241629, COSV101495729; called by mutect2, varscan2
- ABCA9 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ABTB2 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACIN1 | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, varscan2
- ACVR1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ADAD1 | c.1493dup p.F499Ifs*2 | Frame Shift Ins (INS) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 22/164 reads (13%) | called by mutect2, varscan2
- ADAMTS3 | c.1850G>A p.C617Y | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.4012C>G p.Q1338E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADRA2B | c.778del p.E260Rfs*93 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel, varscan2
- AFG3L2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 44/559 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGTR2 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AHNAK | c.16426G>A p.V5476I | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2
- AHNAK2 | c.11642G>A p.G3881D | Missense Mutation (SNP) | VAF 86/454 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALPK3 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ANK1 | c.4095dup p.C1366Lfs*10 | Frame Shift Ins (INS) | VAF 57/444 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2754del p.E919Rfs*4 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- AP3B2 | c.3244G>A p.V1082M (on ENST00000261722; = p.V1076M on NM_004644.5) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- APOBR | c.2201A>G p.Q734R (on ENST00000431282; = p.Q743R on NM_018690.4) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AQR | c.3715G>A p.D1239N | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AQR | c.2102A>C p.H701P | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ARHGAP32 | c.5516C>T p.A1839V (on ENST00000310343 / NM_001378025.1; = p.A1490V on NM_014715.4) | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF26 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARR3 | c.101-2A>G p.X34_splice | Splice Site (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- ASIC5 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPA | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2
- ATAD5 | c.1296del p.K432Nfs*6 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- ATP6V1H | c.1313T>C p.M438T | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BHLHE41 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD4 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, varscan2
- C12orf66 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- C2CD4D | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- C9orf78 | c.708A>G p.I236M | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA7 | c.449del p.L150Wfs*10 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, varscan2
- CACNA2D3 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel
- CALCRL | c.300del p.V101Lfs*35 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- CCDC120 | c.1130del p.P377Rfs*257 | Frame Shift Del (DEL) | VAF 12/124 reads (10%) | called by mutect2, pindel, varscan2
- CCDC153 | c.24del p.K10Rfs*53 | Frame Shift Del (DEL) | VAF 44/241 reads (18%) | called by mutect2, pindel, varscan2
- CCDC168 | c.5650C>A p.L1884I | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CCDC96 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD180 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPB | c.4880T>C p.L1627P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDS1 | c.824del p.K275Rfs*40 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- CDV3 | c.346_347del p.K116Efs*6 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 33/129 reads (26%) | called by mutect2, pindel, varscan2
- CHRNE | c.234+1G>A p.X78_splice | Splice Site (SNP) | VAF 48/728 reads (7%) | called by muse, mutect2
- CIC | c.4586del p.P1529Lfs*91 | Frame Shift Del (DEL) | VAF 64/317 reads (20%) | called by mutect2, varscan2
- CKMT2 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNPY1 | c.82dup p.I28Nfs*6 | Frame Shift Ins (INS) | VAF 31/164 reads (19%) | called by mutect2, pindel, varscan2
- CNTN3 | c.136del p.I46* | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- COL15A1 | c.3284C>A p.P1095H | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COL27A1 | c.2821C>T p.Q941* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- COL3A1 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 26/406 reads (6%) | called by muse, mutect2
- CRACD | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CTCF | c.626del p.K209Rfs*13 | Frame Shift Del (DEL) | VAF 74/534 reads (14%) | called by pindel, varscan2
- CUX1 | c.1430C>T p.T477I (on ENST00000437600 / NM_181500.4; = p.T479I on NM_001913.5) | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CWF19L1 | c.726T>A p.S242R | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CYP2W1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2
- DCAF8L1 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DICER1 | c.5604-5del | Splice Region (DEL) | VAF 92/446 reads (21%) | called by mutect2, pindel, varscan2
- DMKN | c.1359+2T>C p.X453_splice | Splice Site (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- DNAI2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 25/556 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- DNTTIP1 | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 58/352 reads (16%) | called by muse, mutect2, varscan2
- DTX1 | c.1076A>C p.H359P | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DYNC1H1 | c.10686G>A p.W3562* | Nonsense Mutation (SNP) | VAF 140/666 reads (21%) | called by muse, mutect2, varscan2
- ECPAS | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- EDEM1 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4A2 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ELOF1 | c.188-6G>A | Splice Region (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2
- ENOX2 | c.728del p.P243Qfs*17 (on ENST00000338144 / NM_001382520.1; = p.P214Qfs*17 on NM_006375.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 79/332 reads (24%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.669del p.F223Lfs*68 | Frame Shift Del (DEL) | VAF 115/467 reads (25%) | called by mutect2, pindel, varscan2
- EPN1 | c.899dup p.V301Cfs*6 (on ENST00000270460 / NM_001321263.1; = p.V276Cfs*6 on NM_013333.3) | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | called by mutect2, varscan2
- ERMN | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERRFI1 | c.419T>C p.F140S | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FAM120AOS | c.539A>C p.K180T | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FAM135A | c.4205T>A p.L1402* (on ENST00000370479 / NM_001351599.1; = p.L1189* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- FAM163A | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAM47B | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FAM83A | c.961A>G p.S321G | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- FANCM | c.3068T>C p.L1023S | Missense Mutation (SNP) | VAF 32/700 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- FARP1 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT2 | c.10843G>T p.V3615F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAXC | c.184T>C p.W62R | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXO46 | c.1271del p.P424Rfs*34 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by mutect2, pindel, varscan2
- FER1L5 | c.169del p.L57Wfs*34 | Frame Shift Del (DEL) | VAF 39/216 reads (18%) | called by mutect2, pindel, varscan2
- FKBP15 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FKBPL | c.472del p.E158Sfs*3 | Frame Shift Del (DEL) | VAF 51/433 reads (12%) | called by mutect2, pindel, varscan2
- FMN2 | c.2011G>T p.G671* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 25/240 reads (10%) | called by mutect2, pindel, varscan2
- FRMD3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.158); called by muse, mutect2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 31/133 reads (23%) | called by mutect2, varscan2
- FZD7 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- GABRB2 | c.691A>G p.R231G | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2
- GAK | c.1385C>A p.P462H | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- GAREM2 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GCLC | c.505G>A p.G169R (on ENST00000643939; = p.G167R on NM_001498.4) | Missense Mutation (SNP) | VAF 40/530 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- GLB1L | c.1097del p.P366Rfs*5 | Frame Shift Del (DEL) | VAF 27/144 reads (19%) | called by mutect2, pindel, varscan2
- GNL2 | c.1964del p.K655Rfs*50 | Frame Shift Del (DEL) | VAF 25/211 reads (12%) | called by mutect2, pindel, varscan2
- GOLPH3L | c.431-1G>T p.X144_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | called by muse, varscan2
- GPR162 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GPR21 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GPT | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GRAMD1B | c.1841G>A p.G614D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- GRIA2 | c.1672A>G p.S558G | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- GTF3C2 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- GTPBP4 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.11); called by muse, mutect2
- HDHD2 | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2
- HELLS | c.385del p.R129Efs*54 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- HELZ | c.5626G>C p.A1876P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.6799G>A p.A2267T | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HGS | c.909del p.A304Pfs*9 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- HMGB1 | c.551del p.K184Rfs*45 | Frame Shift Del (DEL) | VAF 22/131 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPH2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HUWE1 | c.10006G>A p.V3336I | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYOU1 | c.2430del p.R811Gfs*2 | Frame Shift Del (DEL) | VAF 34/416 reads (8%) | called by mutect2, pindel
- IL12RB2 | c.2138A>G p.Q713R | Missense Mutation (SNP) | VAF 120/528 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- INA | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INSYN1 | c.363dup p.S122Lfs*17 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- IPO4 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2
- IRF6 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGB8 | c.27del p.F9Lfs*81 | Frame Shift Del (DEL) | VAF 18/224 reads (8%) | called by mutect2, pindel
- ITPR1 | c.6419A>G p.E2140G (on ENST00000354582; = p.E2085G on NM_002222.7) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JCAD | c.1770A>T p.E590D | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2
- KANSL2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- KAZN | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | called by muse, mutect2, varscan2
- KCNC2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KCNH1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNH4 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- KCNU1 | c.162del p.K54Nfs*25 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- KIAA2026 | c.6141G>T p.L2047F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- KIF20B | c.2745del p.Q916Sfs*12 (on ENST00000371728 / NM_001284259.2; = p.Q876Sfs*12 on NM_016195.4) | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- KIFC1 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIRREL1 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by mutect2, varscan2
- KMT2B | c.5636dup p.V1880Cfs*92 | Frame Shift Ins (INS) | VAF 45/244 reads (18%) | called by mutect2, pindel, varscan2
- KMT2E | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- KMT5C | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- L3MBTL1 | c.251C>T p.A84V (on ENST00000418998 / NM_001377303.1; = p.A62V on NM_032107.5) | Missense Mutation (SNP) | VAF 50/624 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2
- LACTB | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA3 | c.7738del p.T2580Hfs*68 (on ENST00000313654 / NM_198129.4; = p.T971Hfs*68 on NM_000227.6) | Frame Shift Del (DEL) | VAF 63/302 reads (21%) | called by mutect2, pindel, varscan2
- LASP1 | c.753del p.M252Cfs*42 | Frame Shift Del (DEL) | VAF 55/223 reads (25%) | called by mutect2, pindel, varscan2
- LATS2 | c.1287del p.N430Tfs*3 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel
- LCMT1 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- LIF | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 28/469 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.088); called by muse, mutect2
- LIFR | c.2099del p.F700Sfs*16 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel
- LRRC74B | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MAGEB6B | c.589dup p.R197Kfs*15 | Frame Shift Ins (INS) | VAF 24/297 reads (8%) | called by mutect2, pindel
- MAP3K1 | c.598dup p.E200Gfs*8 | Frame Shift Ins (INS) | VAF 34/318 reads (11%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3236del p.N1079Ifs*3 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4253C>A p.P1418H | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K20 | c.665dup p.N222Kfs*16 | Frame Shift Ins (INS) | VAF 26/129 reads (20%) | called by mutect2, varscan2
- MAPK6 | c.1143T>G p.D381E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAPKAPK5 | c.1178T>C p.L393P | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MAST2 | c.1784del p.X595_splice | Splice Site (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 80/502 reads (16%) | called by mutect2, varscan2
- MEA1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKKS | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, varscan2
- MROH5 | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- MRPL43 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- MST1 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 98/611 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.4253_4254del p.S1418Cfs*19 | Frame Shift Del (DEL) | VAF 49/254 reads (19%) | called by pindel, varscan2
- MYL10 | c.611del p.P204Qfs*42 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel
- NAA10 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- NAP1L2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- NAT10 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NDN | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NEO1 | c.250del p.I84Lfs*10 | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | called by mutect2, pindel, varscan2
- NICN1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | called by pindel, varscan2
- NKX2-3 | c.40_43del p.V14Kfs*4 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- NOMO1 | c.1895-1G>T p.X632_splice | Splice Site (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- NOP53 | c.1368_1369dup p.A457Efs*10 | Frame Shift Ins (INS) | VAF 38/196 reads (19%) | called by mutect2, varscan2
- NOXO1 | c.609G>T p.W203C (on ENST00000397280 / NM_172168.3; = p.W197C on NM_144603.4) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NPRL2 | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NT5E | c.1104+1G>A p.X368_splice | Splice Site (SNP) | VAF 76/454 reads (17%) | called by muse, mutect2, varscan2
- NUP107 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- NUP210 | c.2260C>A p.L754I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NUP42 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUTM2G | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- OBSL1 | c.3099G>T p.E1033D | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR2K2 | c.892del p.I298* (on ENST00000374428; = p.I269* on NM_205859.2) | Frame Shift Del (DEL) | VAF 37/167 reads (22%) | called by mutect2, pindel, varscan2
- OR2V2 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
- OR51F1 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR6C4 | c.8dup p.N3Kfs*7 | Frame Shift Ins (INS) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- OR6C74 | c.200del p.L67* | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- OR6N1 | c.398C>A p.P133Q | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- OSBPL7 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OTOF | c.1757C>A p.T586N | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- P2RX6 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PALM3 | c.812G>T p.R271M (on ENST00000340790; = p.R286M on NM_001145028.2) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PCNX1 | c.1034T>C p.L345S | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDS5B | c.80_82del p.S27_K28delins* | Nonsense Mutation (DEL) | VAF 44/136 reads (32%) | called by mutect2, pindel, varscan2
- PEX6 | c.603_604del p.G202Rfs*39 | Frame Shift Del (DEL) | VAF 103/510 reads (20%) | called by mutect2, pindel, varscan2
- PFAS | c.3245C>T p.A1082V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PFKL | c.1409+2T>C p.X470_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- PGAM2 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 188/736 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PHKG2 | c.913del p.R305Afs*19 | Frame Shift Del (DEL) | VAF 103/492 reads (21%) | called by mutect2, pindel, varscan2
- PIK3CD | c.505del p.L169Cfs*48 | Frame Shift Del (DEL) | VAF 26/294 reads (9%) | called by mutect2, pindel
- PIR | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHG1 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHG7 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, varscan2
- PLRG1 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- PLXNA3 | c.2923T>C p.C975R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PLXNB2 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.164); called by muse, mutect2
- PMM1 | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PNPLA2 | c.824dup p.D276Gfs*31 | Frame Shift Ins (INS) | VAF 88/343 reads (26%) | called by mutect2, pindel, varscan2
- PPEF1 | c.1136del p.G379Afs*18 | Frame Shift Del (DEL) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- PPOX | c.1082del p.P361Lfs*5 | Frame Shift Del (DEL) | VAF 140/620 reads (23%) | called by mutect2, pindel, varscan2
- PRR12 | c.2211_2212del p.C737Wfs*27 (on ENST00000615927; = p.C1558Wfs*27 on NM_020719.3) | Frame Shift Del (DEL) | VAF 80/412 reads (19%) | called by pindel, varscan2
- PTPN5 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PTPRZ1 | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.326); called by muse, mutect2
- PURA | c.159del p.L54Cfs*24 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | called by pindel, varscan2
- QRICH1 | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- RASA1 | c.431_440delinsAAA p.P144Qfs*28 | Frame Shift Del (DEL) | VAF 65/320 reads (20%) | called by pindel, varscan2*
- RASL10A | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RBL1 | c.431dup p.L144Ffs*9 | Frame Shift Ins (INS) | VAF 46/214 reads (21%) | called by mutect2, varscan2
- RDH5 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- RGPD3 | c.5117C>A p.S1706Y | Missense Mutation (SNP) | VAF 124/575 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RGS17 | c.172_173dup p.T59Lfs*10 | Frame Shift Ins (INS) | VAF 33/153 reads (22%) | called by mutect2, varscan2
- RIMBP3B | c.4396del p.L1466Wfs*2 | Frame Shift Del (DEL) | VAF 54/418 reads (13%) | called by pindel, varscan2
- RIPOR2 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROBO1 | c.4430C>T p.T1477I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- RRN3 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RRP36 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RSPH6A | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RUNX1 | c.26C>T p.T9M (on ENST00000344691 / NM_001001890.3; = p.T36M on NM_001754.5) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- S1PR4 | c.30del p.E11Sfs*76 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- S1PR5 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SAMD9L | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCAF4 | c.359dup p.N120Kfs*7 | Frame Shift Ins (INS) | VAF 40/184 reads (22%) | called by mutect2, varscan2
- SCRT2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDF4 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SHH | c.1113C>G p.S371R | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, varscan2
- SLC28A1 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 24/601 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC38A4 | c.1542+1G>A p.X514_splice | Splice Site (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- SLC49A3 | c.1169T>C p.I390T (on ENST00000404286 / NM_001294341.2; = p.I389T on NM_032219.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SLC7A1 | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- SMAD2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 95/465 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SNRK | c.2116T>G p.F706V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A3 | c.3574del p.T1192Qfs*2 | Frame Shift Del (DEL) | VAF 88/512 reads (17%) | called by mutect2, varscan2
- SPNS3 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPTY2D1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 59/244 reads (24%) | called by muse, mutect2, varscan2
- SRGAP1 | c.2567del p.P856Lfs*3 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel
- SRM | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- STAG2 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, varscan2
- STT3A | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SYCP2 | c.4366del p.S1456Afs*9 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- SYNCRIP | c.854del p.N285Tfs*22 | Frame Shift Del (DEL) | VAF 69/299 reads (23%) | called by mutect2, varscan2
- SYNE1 | c.21842C>T p.T7281I (on ENST00000367255 / NM_182961.4; = p.T7210I on NM_033071.3) | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT4 | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAF6 | c.821A>C p.N274T | Missense Mutation (SNP) | VAF 90/494 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TAPBP | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D4 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D9B | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TEX44 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFCP2L1 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TG | c.7345G>T p.E2449* | Nonsense Mutation (SNP) | VAF 143/808 reads (18%) | called by muse, mutect2, varscan2
- TGFBI | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); called by muse, mutect2
- TLE2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- TLR5 | c.2002T>C p.F668L | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM63A | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNIK | c.3952C>T p.H1318Y | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNNT3 | c.752dup p.H252Afs*? (on ENST00000397301 / NM_001367846.1; = p.H241Afs*83 on NM_006757.4) | Frame Shift Ins (INS) | VAF 118/492 reads (24%) | called by mutect2, pindel, varscan2
- TPSG1 | c.122del p.G41Vfs*44 | Frame Shift Del (DEL) | VAF 11/144 reads (8%) | called by mutect2, pindel
- TRIL | c.1181del p.P394Rfs*30 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- TRIM74 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2, varscan2
- TRPM4 | c.3620del p.P1207Lfs*26 | Frame Shift Del (DEL) | VAF 33/396 reads (8%) | called by mutect2, pindel
- TTC3 | c.5144T>A p.I1715N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- TTC4 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- TTLL3 | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2
- TTN | c.5678G>A p.G1893D (on ENST00000591111; = p.G1847D on NM_003319.4) | Missense Mutation (SNP) | VAF 40/353 reads (11%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT3A1 | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- WDR13 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WDR25 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR36 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 20/580 reads (3%) | called by muse, mutect2
- WNK4 | c.3730-1G>A p.X1244_splice | Splice Site (SNP) | VAF 76/325 reads (23%) | called by muse, mutect2, varscan2
- WSCD1 | c.543-2A>G p.X181_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | called by muse, varscan2
- WSCD2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- XRCC4 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZBED3 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2
- ZFHX4 | c.6170del p.P2057Hfs*26 | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | called by mutect2, varscan2
- ZMYM2 | c.3749del p.N1250Ifs*3 | Frame Shift Del (DEL) | VAF 28/232 reads (12%) | called by mutect2, varscan2
- ZNF134 | c.1034A>G p.E345G | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZNF416 | c.1394C>A p.P465H | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF513 | c.1053del p.Q353Rfs*27 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | called by mutect2, pindel, varscan2
- ZNF607 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ZNF654 | c.2084A>C p.E695A | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF74 | c.527T>A p.V176E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF823 | c.1726dup p.T576Nfs*9 | Frame Shift Ins (INS) | VAF 46/224 reads (21%) | called by mutect2, pindel, varscan2
- ZXDB | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ABCC3 | c.2697C>T p.V899= | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- ACTL9 | c.1023C>T p.C341= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs1249003885, COSV61005046; called by muse, mutect2, varscan2
- ADAT3 | c.378G>A p.L126= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2376G>T p.R792= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV60094549; called by muse, mutect2, varscan2
- ADGRB2 | c.3693G>A p.S1231= | Silent (SNP) | VAF 23/304 reads (8%) | catalogued as rs201162344, COSV57075553; called by muse, mutect2
- AKAP6 | c.5001C>A p.S1667= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as COSV99803161; called by muse, mutect2
- AKAP8 | c.933C>T p.Y311= | Silent (SNP) | VAF 62/309 reads (20%) | catalogued as rs201213080; called by muse, mutect2, varscan2
- ANK3 | c.11607C>T p.A3869= | Silent (SNP) | VAF 64/302 reads (21%) | called by muse, mutect2, varscan2
- APOA5 | c.429C>T p.R143= | Silent (SNP) | VAF 70/482 reads (15%) | catalogued as rs754727126; called by muse, mutect2, varscan2
- APOL3 | c.1092T>C p.H364= (on ENST00000349314 / NM_145640.2; = p.H293= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/350 reads (7%) | called by muse, mutect2
- ARHGAP17 | c.2364G>A p.Q788= (on ENST00000289968 / NM_001006634.3; = p.Q710= on NM_018054.6) | Silent (SNP) | VAF 65/307 reads (21%) | catalogued as COSV51505954; called by muse, mutect2, varscan2
- ARID5A | c.1296G>A p.P432= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs940372901; called by muse, mutect2, varscan2
- ASIC3 | c.840C>T p.G280= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1184320736; called by muse, mutect2
- ASTN1 | c.1836T>C p.S612= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- ATF6 | c.834G>A p.A278= | Silent (SNP) | VAF 160/426 reads (38%) | catalogued as rs202091973; called by muse, mutect2, varscan2
- ATP2B3 | c.2925G>A p.T975= | Silent (SNP) | VAF 64/495 reads (13%) | catalogued as rs374228202, COSV99684374; called by muse, mutect2, varscan2
- ATRIP | c.2169G>T p.T723= (on ENST00000320211 / NM_130384.3; = p.T696= on NM_032166.4) | Silent (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- BARX1 | c.342G>A p.A114= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as rs1013682813; called by muse, mutect2, varscan2
- BAZ1B | c.3801A>G p.E1267= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs190533465; called by muse, mutect2, varscan2
- BEAN1 | c.213C>G p.R71= | Silent (SNP) | VAF 81/314 reads (26%) | called by muse, mutect2, varscan2
- BIRC6 | c.150C>G p.A50= | Silent (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
- BPGM | c.435C>T p.C145= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs146970055; called by muse, mutect2
- BRPF1 | c.1626C>T p.S542= | Silent (SNP) | VAF 71/361 reads (20%) | called by muse, mutect2, varscan2
- BTBD6 | c.1356G>A p.V452= | Silent (SNP) | VAF 55/263 reads (21%) | catalogued as rs1203023022; called by muse, mutect2, varscan2
- BZW2 | c.1122C>T p.S374= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs749796554, COSV51755538; called by muse, mutect2, varscan2
- C2CD5 | c.2337G>A p.L779= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100448564; called by muse, mutect2, varscan2
- C6orf132 | c.2514G>A p.P838= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs997736703; called by muse, mutect2, varscan2
- CAND1 | c.1737T>C p.A579= | Silent (SNP) | VAF 30/225 reads (13%) | called by muse, mutect2, varscan2
- CAVIN2 | c.537C>T p.A179= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs753061930; called by muse, mutect2
- CBX4 | c.429G>A p.P143= | Silent (SNP) | VAF 62/357 reads (17%) | catalogued as rs1378654877; called by muse, mutect2, varscan2
- CCDC33 | c.102C>T p.S34= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- CDK13 | c.4299T>C p.P1433= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV51707840; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1153C>T p.L385= | Silent (SNP) | VAF 93/377 reads (25%) | catalogued as rs1368206600; called by muse, mutect2, varscan2
- CENPB | c.724C>T p.L242= | Silent (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- CHRNB2 | c.381C>T p.Y127= | Silent (SNP) | VAF 37/435 reads (9%) | catalogued as rs201024705, COSV63807947; called by muse, mutect2
- CHST3 | c.1377C>T p.A459= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs1338945586, COSV64150939; called by muse, mutect2, varscan2
- CLCA2 | c.1566C>T p.N522= | Silent (SNP) | VAF 61/279 reads (22%) | catalogued as rs775833883, COSV65287473; called by muse, mutect2, varscan2
- COL11A2 | c.2043C>A p.P681= (on ENST00000341947 / NM_080680.3; = p.P574= on NM_080679.2) | Silent (SNP) | VAF 73/266 reads (27%) | catalogued as COSV59501417; called by muse, mutect2, varscan2
- CPAMD8 | c.846G>A p.P282= (on ENST00000651564; = p.P235= on NM_015692.5) | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs773907220; called by muse, mutect2, varscan2
- CPSF2 | c.2013C>T p.S671= | Silent (SNP) | VAF 12/260 reads (5%) | catalogued as rs1209216860; called by muse, mutect2
- CSHL1 | c.642C>T p.R214= (on ENST00000309894 / NM_022581.3; = p.R120= on NM_001318.4) | Silent (SNP) | VAF 105/436 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.9303G>A p.P3101= (on ENST00000520002; = p.P3100= on NM_033225.6) | Silent (SNP) | VAF 62/245 reads (25%) | catalogued as rs761115346, COSV59281702, COSV59317968; called by muse, mutect2, varscan2
- CSMD1 | c.195C>T p.G65= | Silent (SNP) | VAF 72/487 reads (15%) | catalogued as rs747802898, COSV101221099; called by muse, mutect2, varscan2
- DCBLD1 | c.1800C>T p.Y600= | Silent (SNP) | VAF 13/300 reads (4%) | catalogued as rs983995636; called by muse, mutect2
- DCT | c.144G>A p.S48= | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as rs778096555; called by muse, mutect2, varscan2
- DDX17 | c.144G>A p.A48= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- DERPC | c.951G>A p.S317= | Silent (SNP) | VAF 62/249 reads (25%) | catalogued as rs978737356; called by muse, mutect2, varscan2
- DIO2 | c.657C>A p.A219= | Silent (SNP) | VAF 13/323 reads (4%) | called by muse, mutect2
- DNAH7 | c.2100T>C p.A700= | Silent (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- DTX2 | c.429G>T p.V143= | Silent (SNP) | VAF 25/408 reads (6%) | catalogued as COSV56860111; called by muse, mutect2
- ECH1 | c.144T>C p.G48= | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- EFEMP2 | c.1305C>T p.T435= | Silent (SNP) | VAF 42/622 reads (7%) | catalogued as rs1260193001, COSV100337395; called by muse, mutect2
- ENO4 | c.564G>A p.V188= (on ENST00000622726; = p.V187= on NM_001242699.2) | Silent (SNP) | VAF 21/147 reads (14%) | called by muse, varscan2
- EPS8L1 | c.958C>T p.L320= (on ENST00000201647 / NM_133180.3; = p.L193= on NM_017729.3) | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- ERCC6 | c.1794T>C p.H598= | Silent (SNP) | VAF 47/405 reads (12%) | called by muse, mutect2, varscan2
- EXD3 | c.2397G>A p.A799= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs532420019; called by muse, mutect2, varscan2
- F8 | c.6831G>A p.K2277= | Silent (SNP) | VAF 21/330 reads (6%) | called by muse, mutect2
- FASN | c.5808C>T p.G1936= | Silent (SNP) | VAF 67/330 reads (20%) | catalogued as rs145767304; called by muse, mutect2, varscan2
- FBRS | c.978C>A p.A326= (on ENST00000287468; = p.A846= on NM_001105079.3) | Silent (SNP) | VAF 87/313 reads (28%) | called by muse, mutect2, varscan2
- FGB | c.552T>C p.D184= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as rs770695888; called by muse, mutect2, varscan2
- FNDC1 | c.2316G>A p.S772= | Silent (SNP) | VAF 57/284 reads (20%) | called by muse, mutect2, varscan2
- GARS1 | c.1995C>T p.G665= | Silent (SNP) | VAF 147/427 reads (34%) | catalogued as rs1256053017, COSV66827997; called by muse, mutect2, varscan2
- GJD2 | c.460C>T p.L154= | Silent (SNP) | VAF 32/332 reads (10%) | catalogued as rs755084285; called by muse, mutect2
- GOLGA6A | c.631C>T p.L211= | Silent (SNP) | VAF 33/466 reads (7%) | called by muse, mutect2
- GPR149 | c.1893G>A p.L631= | Silent (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- GRM3 | c.870C>T p.R290= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs750137951, COSV64470967; called by muse, mutect2, varscan2
- HADHA | c.1759C>T p.L587= | Silent (SNP) | VAF 80/417 reads (19%) | called by muse, mutect2, varscan2
- HAPLN4 | c.1134C>T p.G378= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as rs1286427799; called by muse, mutect2, varscan2
- HCLS1 | c.654G>A p.P218= | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as rs773755604; called by muse, mutect2, varscan2
- HDAC4 | c.882C>T p.S294= | Silent (SNP) | VAF 28/256 reads (11%) | catalogued as rs911608166, COSV100612898; called by muse, mutect2, varscan2
- HELZ2 | c.5559G>A p.A1853= (on ENST00000467148 / NM_001037335.2; = p.A1284= on NM_033405.3) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs777206475, COSV71295670; called by muse, mutect2, varscan2
- HPSE2 | c.330C>T p.P110= | Silent (SNP) | VAF 21/309 reads (7%) | catalogued as rs993031555, COSV65193658; called by muse, mutect2
- HSPA12B | c.1884C>T p.G628= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs1213652908; called by muse, mutect2, varscan2
- HSPA2 | c.867G>A p.S289= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV55968536, COSV99905090; called by muse, mutect2
- IL16 | c.2703G>A p.E901= (on ENST00000302987 / NM_172217.5; = p.E200= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- IL9R | c.813C>T p.G271= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1368G>A p.P456= (on ENST00000538872 / NM_001170738.2; = p.P153= on NM_015232.1) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs782673474, COSV58289189; called by muse, mutect2, varscan2
- ITGA9 | c.2934C>T p.V978= | Silent (SNP) | VAF 77/687 reads (11%) | catalogued as rs954335075; called by muse, mutect2, varscan2
- JAKMIP3 | c.283C>T p.L95= | Silent (SNP) | VAF 35/226 reads (15%) | catalogued as rs370253977, COSV100059476; called by muse, mutect2, varscan2
- JUP | c.1341C>T p.D447= | Silent (SNP) | VAF 41/233 reads (18%) | called by muse, mutect2, varscan2
- KAT6A | c.4401G>A p.Q1467= | Silent (SNP) | VAF 39/335 reads (12%) | called by muse, mutect2, varscan2
- KCNK1 | c.267C>T p.G89= | Silent (SNP) | VAF 57/213 reads (27%) | catalogued as rs1331634619; called by muse, mutect2, varscan2
- KIAA1549L | c.4896G>A p.E1632= (on ENST00000321505; = p.E1929= on NM_012194.3) | Silent (SNP) | VAF 70/224 reads (31%) | called by muse, mutect2, varscan2
- KIF17 | c.1989C>T p.A663= | Silent (SNP) | VAF 76/387 reads (20%) | catalogued as rs759270785; called by muse, mutect2, varscan2
- KIF26B | c.561C>T p.C187= | Silent (SNP) | VAF 37/334 reads (11%) | catalogued as rs181190211; called by muse, mutect2, varscan2
- KIF4B | c.1293C>T p.N431= | Silent (SNP) | VAF 50/276 reads (18%) | catalogued as rs557606097, COSV101469430; called by muse, mutect2, varscan2
- KLHL36 | c.297C>T p.A99= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as rs80159536; called by muse, mutect2, varscan2
- LAMA4 | c.4911G>A p.V1637= (on ENST00000230538 / NM_001105206.3; = p.V1630= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/390 reads (10%) | called by muse, mutect2, varscan2
- LITAF | c.27G>A p.A9= | Silent (SNP) | VAF 56/411 reads (14%) | catalogued as rs149518815; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- LSMEM2 | c.18C>T p.P6= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as rs782706499, COSV57115439; called by muse, mutect2, varscan2
- LZTS3 | c.828C>T p.S276= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs376979427; called by muse, mutect2, varscan2
- MAGEL2 | c.2019G>A p.P673= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1432056131; called by muse, varscan2
- MANBAL | c.123C>T p.I41= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs372830717; called by muse, mutect2, varscan2
- MATN2 | c.2304C>T p.D768= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as rs377164086; called by muse, mutect2, varscan2
- MBD3 | c.183C>A p.T61= | Silent (SNP) | VAF 42/578 reads (7%) | catalogued as COSV50083207; called by muse, mutect2
- MICALL2 | c.936G>A p.T312= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs770011692; called by muse, mutect2, varscan2
- MTERF4 | c.918C>A p.A306= | Silent (SNP) | VAF 121/569 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.5790G>A p.R1930= | Silent (SNP) | VAF 40/351 reads (11%) | catalogued as rs369859225; called by muse, mutect2, varscan2
- MXRA5 | c.6438G>A p.A2146= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV54228712; called by muse, mutect2, varscan2
- MYL2 | c.303C>T p.N101= | Silent (SNP) | VAF 57/632 reads (9%) | catalogued as rs1317472220, COSV99960630; called by muse, mutect2
- MYO15B | c.8724G>A p.R2908= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- MYO7B | c.2067G>A p.S689= | Silent (SNP) | VAF 42/331 reads (13%) | catalogued as rs879071316; called by muse, mutect2, varscan2
- NEURL1 | c.165C>T p.S55= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs757509316, COSV63913617; called by muse, mutect2
- NIPBL | c.7272C>T p.D2424= | Silent (SNP) | VAF 42/250 reads (17%) | catalogued as rs113988530, COSV56956268; called by muse, varscan2
- NLRP2 | c.1215C>T p.C405= | Silent (SNP) | VAF 110/533 reads (21%) | catalogued as rs1555774209; called by muse, mutect2, varscan2
- NOB1 | c.1047G>A p.L349= | Silent (SNP) | VAF 22/388 reads (6%) | called by muse, mutect2
- NOS1 | c.2781G>A p.G927= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- OAF | c.717G>A p.T239= | Silent (SNP) | VAF 30/388 reads (8%) | catalogued as rs768562737, COSV61109510; called by muse, mutect2
- OLFML2A | c.837C>T p.R279= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs374490177; called by muse, mutect2
- OR10G7 | c.438C>T p.G146= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- OR4K1 | c.159C>A p.S53= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV99579391, COSV99579456; called by muse, varscan2
- OTP | c.210G>A p.P70= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as rs141172285; called by muse, mutect2, varscan2
- PAK6 | c.30T>C p.P10= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs139649727; called by muse, mutect2, varscan2
- PATJ | c.2280G>A p.V760= | Silent (SNP) | VAF 50/236 reads (21%) | called by muse, mutect2, varscan2
- PCDH1 | c.2460G>A p.T820= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as rs763929466, COSV54618017; called by muse, mutect2, varscan2
- PCDHA9 | c.1437G>A p.A479= | Silent (SNP) | VAF 98/905 reads (11%) | catalogued as COSV100969125; called by muse, mutect2, varscan2
- PCDHB9 | c.2112G>A p.S704= | Silent (SNP) | VAF 105/521 reads (20%) | catalogued as COSV53375508; called by muse, mutect2, varscan2
- PCNT | c.8829G>A p.S2943= | Silent (SNP) | VAF 111/412 reads (27%) | catalogued as rs773483379, COSV64024882, COSV64030274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3C2B | c.2448G>A p.Q816= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs755006589; called by muse, mutect2
- PLAA | c.1230T>C p.N410= | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- PLEC | c.13038C>T p.I4346= (on ENST00000322810 / NM_201380.4; = p.I4236= on NM_000445.5) | Silent (SNP) | VAF 25/329 reads (8%) | catalogued as rs372573622; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PLEKHB1 | c.603C>T p.G201= | Silent (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- PLEKHM1 | c.2085C>T p.D695= | Silent (SNP) | VAF 146/669 reads (22%) | called by muse, mutect2, varscan2
185 further variants in this file (0 protein-altering or splice-affecting, 75 silent, 110 other) are not listed here.
